Somatic mutation profile of cancer-model specimen HCM-BROD-0710-C43-85M (Adherent Cell Line, passage 3; aliquot HCM-BROD-0710-C43-85M-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-0710-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.1 years (25,595 days).
Specimen HCM-BROD-0710-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 167516dc-27e2-4107-bcac-a9230acbbcac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0710-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0710-C43-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8ba2a72-7228-46fb-aecf-06c4e284d4a7

The open-access MAF lists 307 somatic variants for this specimen: 204 protein-altering or splice-affecting, 90 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 90, Nonsense Mutation 13, Frame Shift Ins 4, 5'Flank 4, Intron 3, 3'UTR 2, Frame Shift Del 2, 3'Flank 2, 5'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.4294C>T p.R1432* | Nonsense Mutation (SNP) | VAF 138/284 reads (49%) | catalogued as rs587779585, CM013250, COSV58591606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.291-1G>A p.X97_splice | Splice Site (SNP) | VAF 109/111 reads (98%) | hotspot (GDC flag); catalogued as rs112675807, CS004815, CS147061, CS982372, COSV58820323; called by muse, mutect2, varscan2
- ABL2 | c.2017C>T p.R673* (on ENST00000502732 / NM_007314.4; = p.R658* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 176/579 reads (30%) | catalogued as rs374429546; called by muse, mutect2, varscan2
- ADGRA2 | c.3022G>A p.D1008N | Missense Mutation (SNP) | VAF 250/493 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs774085335; called by muse, mutect2, varscan2
- AKR1B15 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs866009184, COSV71152976; called by muse, mutect2, varscan2
- ALOX12B | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as COSV59876071; called by muse, mutect2, varscan2
- AMER1 | c.2954G>T p.S985I | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1187930100; called by muse, mutect2
- ANKRD30A | c.2845G>A p.D949N (on ENST00000611781; = p.D893N on NM_052997.2) | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64622909; called by muse, mutect2, varscan2
- ARL3 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 166/167 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs751601468; called by muse, mutect2, varscan2
- ASIC5 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV73332547; called by muse, mutect2, varscan2
- ATXN7L2 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 205/776 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs772939744, COSV60205175; called by muse, mutect2, varscan2
- BACH1 | c.1813C>A p.H605N | Missense Mutation (SNP) | VAF 128/230 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV54519123; called by mutect2, varscan2
- BCAM | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 181/394 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs569668745, COSV54304706; called by muse, mutect2, varscan2
- BEND3 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 150/322 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782353671; called by muse, varscan2
- BSDC1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 412/634 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs201994378; called by muse, mutect2, varscan2
- C19orf47 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 151/306 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs773570067; called by muse, mutect2, varscan2
- CASR | c.1922G>A p.W641* (on ENST00000490131; = p.W718* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 212/422 reads (50%) | catalogued as COSV56136686; called by muse, mutect2, varscan2
- CBLL2 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 175/384 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs868368528, COSV60370252; called by muse, mutect2, varscan2
- CD300C | c.673T>C p.*225Qext*55 | Nonstop Mutation (SNP) | VAF 44/216 reads (20%) | catalogued as rs749858649; called by muse, mutect2, varscan2
- CHD4 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 118/265 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.851); catalogued as rs762788560; called by muse, mutect2, varscan2
- CPXCR1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 203/426 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52162894; called by muse, mutect2, varscan2
- DACT2 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 165/352 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV64693187; called by muse, mutect2, varscan2
- DSEL | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 176/350 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.076); catalogued as COSV59489992; called by mutect2, varscan2
- EIF4E1B | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 211/213 reads (99%) | catalogued as rs1342984580; called by muse, mutect2, varscan2
- FADS6 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 192/416 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs145096183, COSV59601801; called by muse, mutect2, varscan2
- FBXO40 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 120/258 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV57526473; called by muse, mutect2, varscan2
- FNTB | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 194/364 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212071241, COSV55760527; called by muse, mutect2, varscan2
- FYB2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 198/310 reads (64%) | catalogued as COSV58583196; called by muse, mutect2, varscan2
- GABRA6 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs770297519; called by muse, mutect2, varscan2
- GCC2 | c.4222C>T p.R1408W | Missense Mutation (SNP) | VAF 119/254 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201191345; called by muse, mutect2
- GGT7 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 154/325 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as rs569819094; called by muse, mutect2, varscan2
- GHSR | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.147); catalogued as COSV53841545; called by muse, mutect2, varscan2
- GIPC1 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 173/574 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374322460; called by muse, mutect2, varscan2
- GOLGA4 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs755889799, COSV100728646; called by muse, mutect2, varscan2
- HHLA2 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 167/351 reads (48%) | catalogued as rs1272904239, COSV63320800; called by muse, mutect2, varscan2
- JAK2 | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 61/61 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774138621, COSV67674921; called by muse, mutect2, varscan2
- JAK2 | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777259241; called by muse, mutect2, varscan2
- JCAD | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 150/349 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64757950; called by muse, mutect2, varscan2
- KCNB2 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 172/366 reads (47%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.049); catalogued as COSV73050366; called by muse, mutect2, varscan2
- KIF18A | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV54185320; called by muse, mutect2, varscan2
- KMT2D | c.9851C>T p.S3284F | Missense Mutation (SNP) | VAF 231/476 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV56447565; called by mutect2, varscan2
- KRT14 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 178/350 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs773622623, COSV99390973; called by muse, varscan2
- LCE6A | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 136/384 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs938993602; called by muse, mutect2, varscan2
- LIPI | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT tolerated (0.52); PolyPhen probably damaging (1); catalogued as COSV60715612; called by muse, mutect2, varscan2
- LMBR1L | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV57268612; called by muse, mutect2, varscan2
- LRRIQ1 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376422827, COSV101280677; called by muse, mutect2, varscan2
- MAP3K10 | c.2662C>T p.R888W | Missense Mutation (SNP) | VAF 216/469 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1333936673, COSV53421523; called by muse, mutect2, varscan2
- MAST4 | c.4190C>A p.S1397Y (on ENST00000403625 / NM_001164664.2; = p.S1208Y on NM_015183.3) | Missense Mutation (SNP) | VAF 596/600 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55115217; called by muse, mutect2, varscan2
- ME1 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV100866467; called by muse, mutect2, varscan2
- METTL25 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763803362, COSV50259150; called by muse, mutect2, varscan2
- MOV10L1 | c.3086G>A p.G1029E | Missense Mutation (SNP) | VAF 185/361 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99433565; called by muse, mutect2, varscan2
- MRAP2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 132/256 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57632375; called by muse, mutect2, varscan2
- MYH7 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 218/488 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs730880820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 122/241 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV51784348; called by muse, mutect2, varscan2
- MYO18B | c.3868G>A p.G1290R | Missense Mutation (SNP) | VAF 111/238 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV59129637; called by muse, mutect2, varscan2
- NCAM1 | c.1711G>A p.V571I (on ENST00000316851 / NM_181351.5; = p.V561I on NM_000615.7) | Missense Mutation (SNP) | VAF 122/270 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs370003415, COSV57520141; called by muse, mutect2, varscan2
- NCOR1 | c.2820G>A p.M940I | Missense Mutation (SNP) | VAF 74/74 reads (100%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.885); catalogued as rs773195986; called by muse, mutect2, varscan2
- NFE2L2 | c.1706G>C p.R569P | Missense Mutation (SNP) | VAF 158/295 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67960328; called by muse, mutect2, varscan2
- NLRP4 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 189/348 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as rs1175246779, COSV56709262, COSV56719853; called by muse, mutect2, varscan2
- NPHP3 | c.3299G>A p.G1100D | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758927671; called by muse, mutect2, varscan2
- OR10A7 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 193/397 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760505741; called by muse, mutect2, varscan2
- OR12D3 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 198/406 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780883178, COSV101011422; called by muse, mutect2, varscan2
- OR13C5 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 208/324 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778754351, COSV66164157; called by muse, mutect2, varscan2
- OR1A1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1029042752, COSV58403574; called by muse, mutect2, varscan2
- OR2L5 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 143/448 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs766169928, COSV62364235; called by muse, mutect2, varscan2
- OR4C12 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1555019990; called by muse, mutect2, varscan2
- OR4N2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 93/356 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60050301; called by muse, mutect2, varscan2
- OR51D1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 210/391 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1473413857, COSV62914851; called by muse, mutect2, varscan2
- OR51I1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 170/383 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs373885594; called by muse, mutect2
- OR5C1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 258/763 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65456042; called by muse, mutect2, varscan2
- OR5K3 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as rs923664547; called by muse, mutect2, varscan2
- PAPPA2 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 160/538 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as rs1192409900; called by muse, mutect2, varscan2
- PDGFB | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 172/360 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as COSV58649360; called by muse, mutect2, varscan2
- PLA2G4D | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 170/359 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV51820833; called by muse, mutect2, varscan2
- PTPRC | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV61419376; called by muse, mutect2, varscan2
- PUSL1 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 236/363 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs779407926; called by muse, mutect2, varscan2
- PWWP3B | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 192/413 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV61798632; called by muse, mutect2, varscan2
- PYGO1 | c.182C>G p.P61R | Missense Mutation (SNP) | VAF 127/274 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV100114628; called by muse, mutect2, varscan2
- RERE | c.4106C>T p.P1369L | Missense Mutation (SNP) | VAF 222/663 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs1233073978; called by muse, varscan2
- RIMS2 | c.3806G>A p.G1269E | Missense Mutation (SNP) | VAF 109/313 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs537701932, COSV51678947; called by muse, mutect2, varscan2
- RNF212 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 125/244 reads (51%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs993885644; called by muse, mutect2, varscan2
- SCN11A | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571721216, COSV56565730; called by muse, mutect2, varscan2
- SCYL1 | c.1233C>T p.S411= | Splice Region (SNP) | VAF 124/257 reads (48%) | catalogued as rs377590378; called by muse, mutect2, varscan2
- SETX | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 229/421 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1286335620; called by muse, mutect2, varscan2
- SHANK2 | c.4535C>T p.T1512I | Missense Mutation (SNP) | VAF 172/340 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53619418; called by muse, mutect2, varscan2
- SLC30A10 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 150/501 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63070770; called by muse, mutect2, varscan2
- SLC6A11 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs757265540, COSV54397819; called by muse, mutect2, varscan2
- SLC9A4 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 232/459 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181947037; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 171/359 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100561681; called by muse, mutect2, varscan2
- SYT16 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV70856873; called by muse, mutect2, varscan2
- TGM2 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 183/364 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100821817; called by muse, mutect2, varscan2
- TNK2 | c.3028C>T p.H1010Y | Missense Mutation (SNP) | VAF 198/434 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.193); catalogued as rs1163181869; called by muse, mutect2, varscan2
- TPTE2 | c.529C>T p.R177* (on ENST00000400230 / NM_199254.2; = p.R100* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | catalogued as rs538397448, COSV55016766, COSV55028827; called by muse, mutect2, varscan2
- TTN | c.10390G>A p.E3464K (on ENST00000591111; = p.E3418K on NM_003319.4) | Missense Mutation (SNP) | VAF 72/176 reads (41%) | catalogued as rs773793548, COSV59961451; called by muse, mutect2, varscan2
- TYW1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 176/377 reads (47%) | catalogued as rs769154282, COSV62753704; called by muse, mutect2, varscan2
- ZC3H12D | c.401del p.P134Hfs*51 | Frame Shift Del (DEL) | VAF 89/195 reads (46%) | catalogued as COSV66324648; called by mutect2, pindel*, varscan2
- ABCA8 | c.3018T>A p.D1006E | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ABL1 | c.606T>A p.H202Q | Missense Mutation (SNP) | VAF 384/600 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- ACMSD | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 138/308 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2067G>A p.W689* | Nonsense Mutation (SNP) | VAF 480/713 reads (67%) | called by muse, mutect2, varscan2
- ADPRHL1 | c.3973G>A p.G1325R | Missense Mutation (SNP) | VAF 263/568 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- ADPRHL1 | c.3972G>A p.M1324I | Missense Mutation (SNP) | VAF 264/572 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- ASH1L | c.436T>A p.Y146N | Missense Mutation (SNP) | VAF 210/342 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- BEGAIN | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 304/598 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BUB1B | c.2638C>T p.H880Y | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C13orf42 | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 144/288 reads (50%) | called by muse, mutect2, varscan2
- C1QTNF3 | c.275T>A p.L92Q | Missense Mutation (SNP) | VAF 74/1446 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2
- CA3 | c.181A>C p.N61H | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CBX6 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 233/524 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD40 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH10 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 232/706 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CEP126 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CHD4 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 120/270 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- COL4A2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 130/320 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.107); called by muse, mutect2
- COL5A2 | c.3055G>A p.V1019I | Missense Mutation (SNP) | VAF 116/248 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CROCC2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 182/382 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DENND2C | c.2177C>A p.P726Q (on ENST00000393274 / NM_001256404.2; = p.P669Q on NM_198459.4) | Missense Mutation (SNP) | VAF 186/506 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EHBP1L1 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 128/293 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM234B | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 193/372 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FBXO4 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 24/604 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.198); called by muse, mutect2
- FRK | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 147/335 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSCB | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- GGT7 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 154/331 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- GMNC | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 131/273 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GOLGB1 | c.5628G>T p.Q1876H | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GPRC6A | c.2556G>A p.M852I | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HADHA | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 167/356 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCN2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 95/97 reads (98%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- HECTD4 | c.12554C>T p.A4185V | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- HMX1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 251/484 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- HUS1B | c.707T>A p.L236H | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- IL27RA | c.429C>G p.D143E | Missense Mutation (SNP) | VAF 39/702 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- INSRR | c.3139G>A p.G1047S | Missense Mutation (SNP) | VAF 127/427 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 113/272 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- JCAD | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 216/453 reads (48%) | called by muse, mutect2, varscan2
- KCNG3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 29/590 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KLF15 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 143/318 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KMT5B | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 145/374 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT5B | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 147/375 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LGALS4 | c.67A>T p.I23F | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRN3 | c.1877C>T p.T626I | Missense Mutation (SNP) | VAF 120/250 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.6994G>C p.E2332Q | Missense Mutation (SNP) | VAF 13/479 reads (3%) | called by muse, mutect2
- MCF2 | c.612_613insA p.G205Rfs*20 | Frame Shift Ins (INS) | VAF 98/249 reads (39%) | called by mutect2, pindel, varscan2
- MORC1 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MUC17 | c.3070C>T p.P1024S | Missense Mutation (SNP) | VAF 130/649 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MUC4 | c.9983dup p.L3329Sfs*13 | Frame Shift Ins (INS) | VAF 52/279 reads (19%) | called by pindel, varscan2
- MYO10 | c.1474T>A p.C492S | Missense Mutation (SNP) | VAF 244/727 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO15A | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 106/106 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NAB1 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCAPG2 | c.1419_1420del p.K474Sfs*19 | Frame Shift Del (DEL) | VAF 62/362 reads (17%) | called by pindel, varscan2
- NRXN1 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 161/341 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN1 | c.2003T>G p.V668G | Missense Mutation (SNP) | VAF 187/346 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NXF3 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 198/403 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OBSCN | c.15511C>T p.H5171Y | Missense Mutation (SNP) | VAF 356/599 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- OR52J3 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 143/308 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- OR9Q2 | c.635T>C p.L212S | Missense Mutation (SNP) | VAF 66/380 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OTOG | c.2695G>T p.D899Y | Missense Mutation (SNP) | VAF 168/391 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PAPPA2 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 156/534 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGAP1 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- PLCB2 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 149/286 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PLCH2 | c.4226A>T p.E1409V | Missense Mutation (SNP) | VAF 191/608 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PLEKHG3 | c.1073C>T p.S358F (on ENST00000394691; = p.S414F on NM_001308147.2) | Missense Mutation (SNP) | VAF 147/292 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PNMA2 | c.654G>T p.M218I | Missense Mutation (SNP) | VAF 17/515 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.099); called by muse, mutect2
- PRDM11 | c.946C>T p.P316S (on ENST00000530656 / NM_001359633.1; = p.P282S on NM_001256695.1) | Missense Mutation (SNP) | VAF 151/316 reads (48%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRR23D1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 102/537 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- PSMD1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PUM2 | c.2064G>C p.Q688H | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); called by muse, mutect2
- RAB11FIP1 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 172/378 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RASAL3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 112/424 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- RSRP1 | c.550dup p.T184Nfs*13 | Frame Shift Ins (INS) | VAF 215/439 reads (49%) | called by mutect2, pindel, varscan2
- RXRA | c.973C>T p.L325F | Missense Mutation (SNP) | VAF 444/659 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- RYR2 | c.4300C>T p.P1434S | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SCARF2 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 202/407 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SCEL | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 124/263 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SETD2 | c.6479dup p.H2161Afs*23 | Frame Shift Ins (INS) | VAF 184/521 reads (35%) | called by pindel, varscan2
- SLC30A10 | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 34/832 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC35F3 | c.262A>C p.K88Q (on ENST00000366617 / NM_001300845.1; = p.K157Q on NM_173508.4) | Missense Mutation (SNP) | VAF 63/864 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.17); called by muse, mutect2
- SLITRK2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 261/468 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SLU7 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 209/209 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SORL1 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 134/268 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SSRP1 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SYT16 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 113/288 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- THEMIS2 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC2 | c.3603A>T p.Q1201H | Missense Mutation (SNP) | VAF 91/488 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR4 | c.2093A>T p.E698V (on ENST00000355622 / NM_138554.5; = p.E658V on NM_003266.4) | Missense Mutation (SNP) | VAF 380/571 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- TMC8 | c.1756A>G p.I586V | Missense Mutation (SNP) | VAF 269/551 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM209 | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TNFSF13B | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 153/328 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TPP2 | c.1871G>C p.G624A | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIML2 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 173/363 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- TRPC4 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 130/238 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.57988G>A p.E19330K (on ENST00000591111; = p.E11906K on NM_003319.4) | Missense Mutation (SNP) | VAF 186/380 reads (49%) | PolyPhen benign (0.254); called by muse, mutect2, varscan2
- USP34 | c.8526T>G p.D2842E | Missense Mutation (SNP) | VAF 191/377 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP35 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 152/321 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WASHC2A | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 84/117 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- WDR87 | c.7322G>A p.G2441E | Missense Mutation (SNP) | VAF 142/320 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR87 | c.2875C>G p.L959V | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZBTB5 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZBTB7A | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ZFYVE26 | c.3295G>T p.E1099* | Nonsense Mutation (SNP) | VAF 91/184 reads (49%) | called by muse, mutect2, varscan2
- ZMYM4 | c.3193C>T p.Q1065* | Nonsense Mutation (SNP) | VAF 57/203 reads (28%) | called by muse, mutect2, varscan2
- ZNF367 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 207/361 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF404 | c.1111A>C p.T371P | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, varscan2
- ZNF74 | c.1058T>G p.V353G | Missense Mutation (SNP) | VAF 249/522 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ABCA13 | c.14586G>A p.K4862= | Silent (SNP) | VAF 171/349 reads (49%) | called by muse, mutect2, varscan2
- ABL2 | c.2016C>T p.F672= (on ENST00000502732 / NM_007314.4; = p.F657= on NM_005158.5) | Silent (SNP) | VAF 175/581 reads (30%) | catalogued as rs867406798; called by muse, mutect2, varscan2
- ADAM19 | c.1719G>A p.G573= | Silent (SNP) | VAF 269/269 reads (100%) | catalogued as COSV57432464; called by muse, mutect2, varscan2
- ADAM33 | c.2304C>T p.P768= | Silent (SNP) | VAF 184/474 reads (39%) | called by muse, mutect2
- ADAM7 | c.954C>T p.I318= | Silent (SNP) | VAF 114/256 reads (45%) | catalogued as COSV51545823, COSV99442708; called by muse, mutect2, varscan2
- ADGRB2 | c.2037G>A p.E679= | Silent (SNP) | VAF 356/535 reads (67%) | catalogued as COSV57076300; called by muse, mutect2, varscan2
- ADGRV1 | c.9021G>A p.L3007= | Silent (SNP) | VAF 239/239 reads (100%) | called by muse, mutect2, varscan2
- ALG10 | c.637C>T p.L213= | Silent (SNP) | VAF 173/354 reads (49%) | catalogued as rs1277639824; called by muse, mutect2, varscan2
- ALOX12B | c.621G>A p.T207= | Silent (SNP) | VAF 108/109 reads (99%) | catalogued as COSV59874227; called by muse, mutect2, varscan2
- AMMECR1 | c.249C>T p.I83= | Silent (SNP) | VAF 238/535 reads (44%) | catalogued as rs1235089425; called by muse, varscan2
- BTBD11 | c.2496C>T p.I832= (on ENST00000280758 / NM_001018072.2; = p.I369= on NM_001017523.2) | Silent (SNP) | VAF 172/332 reads (52%) | catalogued as rs758128980, COSV55024804; called by muse, varscan2
- BUB1B | c.2637C>T p.V879= | Silent (SNP) | VAF 93/235 reads (40%) | called by muse, mutect2, varscan2
- C17orf80 | c.396C>T p.F132= | Silent (SNP) | VAF 119/238 reads (50%) | called by muse, mutect2, varscan2
- C1QTNF12 | c.156G>A p.E52= | Silent (SNP) | VAF 429/673 reads (64%) | called by muse, mutect2, varscan2
- CA2 | c.642C>T p.P214= | Silent (SNP) | VAF 33/246 reads (13%) | called by muse, mutect2, varscan2
- CARD11 | c.2577C>T p.D859= | Silent (SNP) | VAF 204/429 reads (48%) | catalogued as rs140815848, COSV62755416; called by muse, mutect2, varscan2
- CBX6 | c.1080C>T p.P360= | Silent (SNP) | VAF 234/523 reads (45%) | catalogued as rs895128516; called by muse, mutect2, varscan2
- CD1A | c.906C>T p.F302= | Silent (SNP) | VAF 253/379 reads (67%) | catalogued as rs1318762759, COSV56861264; called by muse, mutect2, varscan2
- CD46 | c.156C>G p.P52= | Silent (SNP) | VAF 23/560 reads (4%) | called by muse, mutect2
- CEP162 | c.3840T>A p.S1280= | Silent (SNP) | VAF 94/204 reads (46%) | called by muse, mutect2, varscan2
- CHN1 | c.870G>A p.R290= | Silent (SNP) | VAF 115/262 reads (44%) | catalogued as rs1292344281; called by muse, mutect2, varscan2
- CNTNAP5 | c.1482C>A p.P494= | Silent (SNP) | VAF 80/195 reads (41%) | catalogued as COSV70490746; called by muse, mutect2, varscan2
- COL4A6 | c.4887G>A p.R1629= | Silent (SNP) | VAF 280/612 reads (46%) | catalogued as COSV100564773; called by muse, mutect2, varscan2
- DAPK1 | c.3393C>T p.I1131= | Silent (SNP) | VAF 233/726 reads (32%) | catalogued as rs765353398, COSV63786799; called by muse, mutect2, varscan2
- DNAH7 | c.8937A>T p.I2979= | Silent (SNP) | VAF 93/176 reads (53%) | called by muse, mutect2, varscan2
- DOCK5 | c.573C>G p.S191= | Silent (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- DPF2 | c.489C>T p.F163= | Silent (SNP) | VAF 149/310 reads (48%) | catalogued as rs1420017796; called by muse, mutect2, varscan2
- DSCAM | c.327G>A p.G109= | Silent (SNP) | VAF 90/210 reads (43%) | catalogued as COSV68638075; called by muse, mutect2, varscan2
- ERO1A | c.1033C>T p.L345= | Silent (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- FADS3 | c.723C>T p.F241= | Silent (SNP) | VAF 103/231 reads (45%) | catalogued as COSV53877663; called by muse, mutect2, varscan2
- FAM160B2 | c.1515C>T p.T505= | Silent (SNP) | VAF 143/315 reads (45%) | catalogued as rs371113614; called by muse, mutect2, varscan2
- FAM47C | c.114G>A p.L38= | Silent (SNP) | VAF 281/571 reads (49%) | catalogued as COSV63726479; called by muse, mutect2, varscan2
- FAT3 | c.882G>A p.A294= | Silent (SNP) | VAF 151/340 reads (44%) | catalogued as rs200428460, COSV53121432; called by muse, mutect2, varscan2
- FER1L6 | c.5523C>T p.F1841= | Silent (SNP) | VAF 310/484 reads (64%) | catalogued as COSV67550086; called by muse, mutect2, varscan2
- FLT1 | c.165G>A p.G55= | Silent (SNP) | VAF 120/239 reads (50%) | catalogued as rs1309467103; called by muse, mutect2, varscan2
- FSD2 | c.963A>T p.I321= | Silent (SNP) | VAF 92/222 reads (41%) | called by muse, mutect2, varscan2
- GDE1 | c.462C>T p.I154= | Silent (SNP) | VAF 119/258 reads (46%) | called by muse, mutect2, varscan2
- GPX2 | c.135G>A p.R45= | Silent (SNP) | VAF 154/300 reads (51%) | catalogued as rs772907040; called by muse, mutect2, varscan2
- GRIA2 | c.1779G>A p.G593= | Silent (SNP) | VAF 118/281 reads (42%) | catalogued as COSV52390550, COSV52392955; called by muse, mutect2, varscan2
- GRK1 | c.513C>T p.F171= | Silent (SNP) | VAF 248/494 reads (50%) | catalogued as rs1470677060, COSV59553636; called by muse, mutect2, varscan2
- HEPHL1 | c.1707T>C p.D569= | Silent (SNP) | VAF 85/182 reads (47%) | called by muse, mutect2, varscan2
- IGF2R | c.1335T>G p.T445= | Silent (SNP) | VAF 78/186 reads (42%) | called by muse, mutect2, varscan2
- LAMA1 | c.8628G>A p.P2876= | Silent (SNP) | VAF 174/357 reads (49%) | catalogued as rs547747946; called by muse, mutect2, varscan2
- LCT | c.3834G>A p.L1278= | Silent (SNP) | VAF 153/355 reads (43%) | catalogued as COSV51547126; called by muse, mutect2, varscan2
- MAPKAP1 | c.870C>T p.S290= | Silent (SNP) | VAF 196/301 reads (65%) | called by muse, mutect2, varscan2
- MBD5 | c.3423T>C p.S1141= | Silent (SNP) | VAF 14/413 reads (3%) | called by muse, mutect2
- MBIP | c.300T>C p.A100= | Silent (SNP) | VAF 98/215 reads (46%) | called by muse, mutect2, varscan2
- MTRNR2L7 | c.69G>A p.Q23= | Silent (SNP) | VAF 91/232 reads (39%) | called by muse, mutect2
- MUC16 | c.38475C>T p.T12825= | Silent (SNP) | VAF 159/232 reads (69%) | called by muse, mutect2, varscan2
- MUC3A | c.8067C>T p.I2689= | Silent (SNP) | VAF 122/732 reads (17%) | catalogued as COSV60222520; called by muse, mutect2
- MYOCD | c.1446C>T p.F482= | Silent (SNP) | VAF 241/242 reads (100%) | catalogued as rs747325331; called by muse, mutect2, varscan2
- NUTM2G | c.60C>T p.T20= | Silent (SNP) | VAF 130/342 reads (38%) | called by muse, mutect2, varscan2
- OR2L3 | c.180C>T p.F60= | Silent (SNP) | VAF 134/466 reads (29%) | catalogued as COSV63454535; called by muse, mutect2, varscan2
- OR4D9 | c.90C>T p.F30= | Silent (SNP) | VAF 153/295 reads (52%) | called by muse, mutect2, varscan2
- OR51D1 | c.126C>T p.F42= | Silent (SNP) | VAF 198/402 reads (49%) | catalogued as rs1031689978; called by muse, mutect2, varscan2
- OR5BS1P | c.186C>T p.F62= | Silent (SNP) | VAF 194/371 reads (52%) | called by muse, mutect2, varscan2
- PACS1 | c.1419G>A p.L473= | Silent (SNP) | VAF 172/363 reads (47%) | called by muse, mutect2, varscan2
- PDXDC1 | c.1788C>T p.A596= | Silent (SNP) | VAF 116/277 reads (42%) | called by muse, mutect2, varscan2
- PIK3C2G | c.360G>A p.T120= | Silent (SNP) | VAF 158/277 reads (57%) | catalogued as rs1342910617; called by muse, mutect2, varscan2
- PIWIL1 | c.225G>A p.S75= | Silent (SNP) | VAF 88/182 reads (48%) | catalogued as rs374469378; called by muse, mutect2, varscan2
- PLEKHM3 | c.2133C>T p.F711= | Silent (SNP) | VAF 125/263 reads (48%) | called by muse, mutect2, varscan2
- PPP2R3B | c.117C>T p.I39= | Silent (SNP) | VAF 267/567 reads (47%) | called by muse, mutect2, varscan2
- PRKD3 | c.2244C>T p.L748= | Silent (SNP) | VAF 127/275 reads (46%) | called by muse, mutect2, varscan2
- PRR23C | c.588G>A p.G196= | Silent (SNP) | VAF 194/401 reads (48%) | catalogued as rs1278649469, COSV101356490; called by muse, mutect2, varscan2
- PTGS2 | c.84C>T p.N28= | Silent (SNP) | VAF 88/328 reads (27%) | catalogued as rs1366501556; called by muse, mutect2, varscan2
- PTPN13 | c.1527C>T p.I509= | Silent (SNP) | VAF 129/270 reads (48%) | catalogued as COSV57401681; called by muse, mutect2, varscan2
- RBBP8NL | c.798C>T p.F266= | Silent (SNP) | VAF 128/245 reads (52%) | catalogued as rs1358698882; called by muse, mutect2, varscan2
- RNF20 | c.996T>C p.L332= | Silent (SNP) | VAF 110/348 reads (32%) | called by muse, mutect2, varscan2
- SALL1 | c.849C>T p.S283= | Silent (SNP) | VAF 179/366 reads (49%) | catalogued as COSV51756097; called by muse, mutect2, varscan2
- SEMA3G | c.234C>A p.L78= | Silent (SNP) | VAF 195/402 reads (49%) | called by muse, mutect2, varscan2
- SEMA7A | c.624C>T p.G208= | Silent (SNP) | VAF 179/374 reads (48%) | catalogued as rs369347333; called by muse, mutect2, varscan2
- SERPINI1 | c.897G>A p.Q299= | Silent (SNP) | VAF 77/141 reads (55%) | called by muse, mutect2, varscan2
- SETX | c.438C>T p.S146= | Silent (SNP) | VAF 229/421 reads (54%) | called by muse, mutect2, varscan2
- SIGLEC8 | c.249C>T p.N83= | Silent (SNP) | VAF 183/416 reads (44%) | catalogued as rs1568516190; called by muse, mutect2, varscan2
- SKAP1 | c.747C>T p.P249= | Silent (SNP) | VAF 168/379 reads (44%) | called by muse, mutect2, varscan2
- SLC10A2 | c.219C>T p.L73= | Silent (SNP) | VAF 208/439 reads (47%) | catalogued as COSV99807656; called by muse, mutect2, varscan2
- SMYD1 | c.420G>A p.G140= | Silent (SNP) | VAF 203/387 reads (52%) | called by muse, mutect2, varscan2
- SMYD2 | c.492C>T p.L164= | Silent (SNP) | VAF 185/461 reads (40%) | catalogued as rs770920046; called by muse, mutect2, varscan2
- SNAP91 | c.1485C>T p.L495= | Silent (SNP) | VAF 178/341 reads (52%) | called by muse, mutect2, varscan2
- SPEF2 | c.4992C>T p.S1664= | Silent (SNP) | VAF 387/597 reads (65%) | called by muse, mutect2, varscan2
- SVEP1 | c.939G>A p.G313= | Silent (SNP) | VAF 140/418 reads (33%) | called by muse, mutect2, varscan2
- TENM3 | c.9G>A p.V3= | Silent (SNP) | VAF 88/178 reads (49%) | catalogued as COSV101305334; called by muse, mutect2, varscan2
- TMCC3 | c.1341T>C p.L447= | Silent (SNP) | VAF 174/369 reads (47%) | called by muse, mutect2, varscan2
- TMIGD1 | c.417G>A p.V139= | Silent (SNP) | VAF 98/213 reads (46%) | called by muse, mutect2, varscan2
- TRPC7 | c.1491G>A p.T497= | Silent (SNP) | VAF 435/436 reads (100%) | catalogued as rs1272174809; called by muse, mutect2, varscan2
- VPS35L | c.2763G>A p.Q921= | Silent (SNP) | VAF 98/242 reads (40%) | catalogued as rs777311864; called by muse, mutect2, varscan2
- WASHC2A | c.1146C>T p.P382= | Silent (SNP) | VAF 84/117 reads (72%) | catalogued as rs1451463455; called by muse, mutect2, varscan2
- WDR64 | c.3027C>T p.F1009= | Silent (SNP) | VAF 248/381 reads (65%) | catalogued as rs749470958; called by muse, mutect2, varscan2
- ZFHX4 | c.6429C>T p.I2143= | Silent (SNP) | VAF 148/258 reads (57%) | catalogued as COSV50495484; called by muse, mutect2, varscan2
- ZNF430 | c.606G>A p.K202= | Silent (SNP) | VAF 134/198 reads (68%) | catalogued as COSV99842068; called by muse, mutect2, varscan2
- ABTB1 | c.*299C>T | 3'UTR (SNP) | VAF 190/412 reads (46%) | catalogued as rs773878210; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915174 C>T | 5'Flank (SNP) | VAF 159/376 reads (42%) | catalogued as rs762491934, COSV58124328; called by muse, mutect2, varscan2
- C4orf50 | c.-53C>T | 5'UTR (SNP) | VAF 142/298 reads (48%) | called by muse, mutect2
- C4orf50 | chr4:5990198 G>A | 5'Flank (SNP) | VAF 152/330 reads (46%) | catalogued as rs1426995796; called by muse, mutect2, varscan2
- CLASP1 | chr2:121649899 C>T | 5'Flank (SNP) | VAF 134/297 reads (45%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22900991 C>G | 3'Flank (SNP) | VAF 105/633 reads (17%) | called by muse, mutect2, varscan2
- LTN1 | chr21:28992921 T>C | 5'Flank (SNP) | VAF 122/268 reads (46%) | called by muse, mutect2, varscan2
- NEBL | c.164+46321G>A | Intron (SNP) | VAF 186/397 reads (47%) | called by muse, mutect2, varscan2
- NPAP1L | n.449C>T | RNA (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1372-87046C>G | Intron (SNP) | VAF 130/266 reads (49%) | called by muse, mutect2
- PUDP | c.511-7298G>A | Intron (SNP) | VAF 141/346 reads (41%) | called by muse, mutect2, varscan2
- SLC9A3 | c.*225G>A | 3'UTR (SNP) | VAF 345/782 reads (44%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26672741 G>A | 3'Flank (SNP) | VAF 127/280 reads (45%) | called by muse, mutect2, varscan2
